National Lung Screening Trial (NLST) participant 207541 — screening results and CT findings
Open-access record from the public subset of National Lung Screening Trial clinical data distributed by the NCI Imaging Data Commons (release v24, collection nlst). NLST enrolled current and former heavy smokers aged 55–74 in 2002–2004 and randomised them to three annual screens (T0, T1, T2) with low-dose CT or chest radiography, with follow-up through 2009. Coded values are written out from the NLST data dictionaries; day counts are days from randomisation.
https://doi.org/10.7937/TCIA.HMQ8-J677

Participant
Age at randomisation: 71 years; Gender: male; Race: White; Cigarette smoking status at randomisation: former smoker (to be eligible, former smokers had quit within the previous 15 years); Enrolled through an American College of Radiology Imaging Network (ACRIN) centre (from the participant ID range).

Screening results (official result of each annual screen after comparison with prior images; this participant has CT screening exam records, so these are low-dose CT screens)
- T0 (day 0): Positive, change unspecified: nodule(s) >= 4 mm or enlarging nodule(s), mass(es), or other non-specific abnormalities suspicious for lung cancer. Exam quality: diagnostic CT; technique as recorded on the form: 120 kVp, 35 effective mAs, display field of view 39 cm, reconstruction filter Siemens, other.
- T1 (day 365): Positive, no significant change: stable abnormalities potentially related to lung cancer, unchanged since the prior screening exam. Isolation read, before comparison with prior images: positive (nodule(s) >= 4 mm, mass or other suspicious abnormality). Exam quality: diagnostic CT; technique as recorded on the form: 120 kVp, 34 effective mAs, display field of view 38 cm, reconstruction filter Siemens, other.
- T2 (day 777): Positive, other. Isolation read, before comparison with prior images: positive (nodule(s) >= 4 mm, mass or other suspicious abnormality). Exam quality: diagnostic CT; technique as recorded on the form: 120 kVp, 34 effective mAs, display field of view 43 cm, reconstruction filter Siemens, other.

Abnormalities recorded by the reading radiologist on the CT screens (12 abnormalities; numbered within each screening year; size, margins, attenuation and location were collected only for non-calcified nodules or masses of at least 4 mm; interval-change items come from the comparison read)
- T0 abnormality 1: Non-calcified nodule or mass (opacity >= 4 mm diameter); epicentre in the right middle lobe; longest diameter 5 mm, longest perpendicular diameter 3 mm; margins smooth; predominant attenuation soft tissue; greatest diameter on CT slice 99.
- T0 abnormality 2: Non-calcified nodule or mass (opacity >= 4 mm diameter); epicentre in the left lower lobe; longest diameter 7 mm, longest perpendicular diameter 7 mm; margins smooth; predominant attenuation soft tissue; greatest diameter on CT slice 175.
- T1 abnormality 1: Non-calcified nodule or mass (opacity >= 4 mm diameter); epicentre in the right middle lobe; longest diameter 4 mm, longest perpendicular diameter 2 mm; margins smooth; predominant attenuation soft tissue; greatest diameter on CT slice 93; pre-existing on earlier images (earliest visible day 0); no interval growth; no suspicious change in attenuation.
- T1 abnormality 2: Non-calcified nodule or mass (opacity >= 4 mm diameter); epicentre in the left lower lobe; longest diameter 6 mm, longest perpendicular diameter 6 mm; margins smooth; predominant attenuation soft tissue; greatest diameter on CT slice 165; pre-existing on earlier images (earliest visible day 0); no interval growth; no suspicious change in attenuation.
- T1 abnormality 3: Other minor abnormality noted.
- T1 abnormality 4: Other minor abnormality noted.
- T2 abnormality 1: Non-calcified nodule or mass (opacity >= 4 mm diameter); epicentre in the right middle lobe; longest diameter 4 mm, longest perpendicular diameter 2 mm; margins smooth; predominant attenuation soft tissue; greatest diameter on CT slice 101; pre-existing on earlier images (earliest visible day 0); no interval growth; no suspicious change in attenuation.
- T2 abnormality 2: Non-calcified nodule or mass (opacity >= 4 mm diameter); epicentre in the left lower lobe; longest diameter 6 mm, longest perpendicular diameter 6 mm; margins smooth; predominant attenuation soft tissue; greatest diameter on CT slice 173; pre-existing on earlier images (earliest visible day 0); no interval growth; no suspicious change in attenuation.
- T2 abnormality 3: Non-calcified nodule or mass (opacity >= 4 mm diameter); epicentre in the left lower lobe; longest diameter 6 mm, longest perpendicular diameter 5 mm; margins poorly defined; predominant attenuation mixed; greatest diameter on CT slice 154.
- T2 abnormality 4: Other potentially significant abnormality above the diaphragm; new (not pre-existing on earlier images).
- T2 abnormality 5: Other minor abnormality noted.
- T2 abnormality 6: Other minor abnormality noted.

Follow-up
No confirmed lung cancer during the trial; Last known free of lung cancer: day 2,515.
